Somatic mutation profile of tumor specimen C3L-00416-02 (aliquot CPT0010110006) from CPTAC case C3L-00416, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 62.0 years (22,653 days).
Specimen C3L-00416-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec8a3688-7a11-48e8-9bff-e2c15de3c8d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00416-31 (Blood Derived Normal), aliquot CPT0019870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50d0f49a-6846-4310-bcfe-7efbeb466645

The open-access MAF lists 121 somatic variants for this specimen: 80 protein-altering or splice-affecting, 29 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 29, Frame Shift Del 10, Nonsense Mutation 5, Intron 5, RNA 4, 3'UTR 1, 3'Flank 1, Splice Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 7/62 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- ACE | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 46/430 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as rs140129129; called by muse, mutect2, varscan2
- AMBN | c.1127C>G p.P376R | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.664); catalogued as COSV59827164; called by muse, mutect2, varscan2
- ARSL | c.331C>G p.R111G | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.106); catalogued as COSV101140565; called by muse, mutect2
- C19orf44 | c.1300del p.E434Sfs*28 | Frame Shift Del (DEL) | VAF 19/135 reads (14%) | catalogued as COSV55611022; called by mutect2, pindel, varscan2
- CFAP54 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs977453151; called by muse, mutect2, varscan2
- CTSA | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 62/616 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs766490643, COSV51943174; called by muse, mutect2
- EP400 | c.7937G>A p.R2646Q | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.983); catalogued as rs372924222; called by muse, mutect2, varscan2
- FGD2 | c.1361A>T p.Q454L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs756612292; called by muse, mutect2, varscan2
- MAPT | c.691G>A p.A231T (on ENST00000262410 / NM_001377265.1; = p.A156T on NM_016835.4) | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.16); catalogued as COSV99043696; called by muse, mutect2, varscan2
- MLXIP | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs756776307, COSV100039169, COSV59834782; called by muse, mutect2
- MPND | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs747112102, COSV53658491; called by muse, mutect2
- MTO1 | c.1952A>G p.H651R (on ENST00000370300 / NM_133645.3; = p.H626R on NM_012123.4) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1368525535; called by muse, mutect2, varscan2
- MVD | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV56330023; called by muse, mutect2, varscan2
- NPSR1 | c.609C>A p.D203E | Missense Mutation (SNP) | VAF 76/454 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.371); catalogued as rs150717138; called by muse, mutect2, varscan2
- PCDHA13 | c.1123T>C p.S375P | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs1301270294; called by muse, mutect2, varscan2
- PKD2 | c.1492C>G p.H498D | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs1553926080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRX | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs142884199; called by muse, mutect2
- RACK1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV65174291; called by muse, mutect2, varscan2
- RELN | c.4369A>C p.K1457Q | Missense Mutation (SNP) | VAF 15/404 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs890007891; ClinVar: uncertain significance; called by muse, mutect2
- SAV1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV61204562; called by muse, mutect2, varscan2
- SIPA1L3 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55911804, COSV55916187; called by muse, mutect2
- SMIM24 | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs998683000; called by muse, mutect2, varscan2
- TMUB1 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as rs1433900233; called by muse, mutect2, varscan2
- WNK3 | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs111417684; called by muse, varscan2
- ZNF727 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs573399407; called by muse, mutect2
- AC092143.1 | c.1382A>G p.D461G | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP21 | c.5811_5823del p.N1938Ifs*25 | Frame Shift Del (DEL) | VAF 34/152 reads (22%) | called by mutect2, pindel, varscan2
- ATF7 | c.644C>T p.T215I (on ENST00000548446 / NM_001366555.2; = p.T204I on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- ATP6V1B2 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ATP7B | c.2956T>C p.S986P | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BAP1 | c.1853del p.P618Lfs*5 | Frame Shift Del (DEL) | VAF 48/314 reads (15%) | called by mutect2, pindel, varscan2
- C8orf34 | c.1327+1G>T p.X443_splice | Splice Site (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- CACNA1S | c.2580G>C p.K860N | Missense Mutation (SNP) | VAF 62/642 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- CACNA2D2 | c.2984T>A p.F995Y (on ENST00000479441 / NM_001174051.3; = p.F988Y on NM_006030.4) | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- CDC37L1 | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, varscan2
- CDKN2A | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 83/464 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- COL5A1 | c.3220A>T p.K1074* | Nonsense Mutation (SNP) | VAF 56/521 reads (11%) | called by muse, mutect2, varscan2
- COMMD10 | c.393_397del p.C132Afs*9 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel
- CREBBP | c.3745G>A p.V1249M | Missense Mutation (SNP) | VAF 64/433 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DLG5 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- DMD | c.7320G>C p.Q2440H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DPY19L3 | c.488T>C p.L163S | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- DYNC2H1 | c.7140+1del | Frame Shift Del (DEL) | VAF 29/122 reads (24%) | called by mutect2, pindel
- GDF5 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 82/389 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- HAO2 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 52/317 reads (16%) | called by muse, mutect2, varscan2
- HMBOX1 | c.192G>T p.R64S | Missense Mutation (SNP) | VAF 74/413 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); called by muse, varscan2
- IGHV1-69 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- INPP5B | c.1643A>G p.D548G (on ENST00000373023; = p.D468G on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- IQGAP2 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- IRAG1 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNA6 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD3 | c.930G>A p.W310* | Nonsense Mutation (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- LSG1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MICAL2 | c.1258G>C p.D420H | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEB | c.15646T>A p.L5216M | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- NEK10 | c.2923_2927del p.H975* | Frame Shift Del (DEL) | VAF 22/143 reads (15%) | called by mutect2, pindel, varscan2
- NPTX1 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR1N2 | c.803C>G p.T268S | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.066); called by muse, mutect2
- PEX3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by mutect2, varscan2
- PIK3CD | c.2415del p.L806Wfs*3 | Frame Shift Del (DEL) | VAF 42/404 reads (10%) | called by mutect2, pindel
- POLR2G | c.402T>C p.D134= | Splice Region (SNP) | VAF 29/157 reads (18%) | called by muse, mutect2, varscan2
- PTH2 | c.40del p.L14Cfs*74 | Frame Shift Del (DEL) | VAF 32/244 reads (13%) | called by pindel, varscan2
- RAB3C | c.20T>C p.M7T | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS14 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEPTIN3 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETD2 | c.7641C>A p.Y2547* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.2002C>A p.L668I (on ENST00000308713 / NM_001114099.3; = p.L598I on NM_012410.4) | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SSC4D | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TACC2 | c.2815C>T p.Q939* | Nonsense Mutation (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- TACC3 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TIAM2 | c.4404C>G p.D1468E (on ENST00000529824; = p.D1439E on NM_012454.3) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); called by muse, mutect2
- TLCD3B | c.580del p.A194Pfs*2 | Frame Shift Del (DEL) | VAF 57/378 reads (15%) | called by mutect2, pindel, varscan2
- TLX3 | c.580G>C p.A194P | Missense Mutation (SNP) | VAF 174/542 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMBIM4 | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNKS | c.1213C>G p.P405A | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); called by muse, mutect2
- TTC37 | c.3409G>T p.D1137Y | Missense Mutation (SNP) | VAF 57/520 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13C | c.11211del p.K3737Nfs*2 (on ENST00000644861 / NM_020821.3; = p.K3694Nfs*2 on NM_017684.5) | Frame Shift Del (DEL) | VAF 46/325 reads (14%) | called by mutect2, pindel, varscan2
- ZNF229 | c.679T>C p.C227R | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2
- ZNF516 | c.2077T>A p.F693I | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AC005324.2 | c.36G>A p.L12= | Silent (SNP) | VAF 47/206 reads (23%) | called by muse, mutect2, varscan2
- AGFG2 | c.861C>T p.A287= | Silent (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- ANG | c.276C>T p.N92= | Silent (SNP) | VAF 19/433 reads (4%) | called by muse, mutect2
- AP1M1 | c.720G>A p.Q240= | Silent (SNP) | VAF 26/141 reads (18%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.1182G>A p.P394= | Silent (SNP) | VAF 14/282 reads (5%) | catalogued as rs1297276165, COSV100327871; called by muse, mutect2
- DHX30 | c.312C>T p.S104= (on ENST00000445061 / NM_138615.3; = p.S65= on NM_014966.3) | Silent (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- FAR1 | c.1278G>A p.R426= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs1343551158; called by muse, mutect2, varscan2
- FERD3L | c.288G>A p.R96= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV51762920, COSV99284975; called by muse, mutect2, varscan2
- GLI3 | c.3888C>T p.G1296= | Silent (SNP) | VAF 22/170 reads (13%) | catalogued as COSV101229971; called by muse, mutect2, varscan2
- IQCE | c.477G>A p.V159= | Silent (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- KCNH7 | c.3225A>G p.T1075= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- KMT2D | c.8598G>A p.E2866= | Silent (SNP) | VAF 100/446 reads (22%) | catalogued as rs373085015; called by muse, mutect2, varscan2
- MAN2C1 | c.2022G>A p.Q674= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV51250093; called by muse, mutect2, varscan2
- MUC1 | c.3078T>C p.H1026= (on ENST00000611571 / NM_001371720.1; = p.H239= on NM_001204285.2) | Silent (SNP) | VAF 127/590 reads (22%) | called by muse, mutect2, varscan2
- MUC22 | c.1179C>A p.G393= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs1449765197; called by muse, mutect2, varscan2
- MYH13 | c.5061G>A p.E1687= | Silent (SNP) | VAF 58/296 reads (20%) | catalogued as COSV99354123; called by muse, mutect2, varscan2
- NRK | c.1422A>C p.A474= | Silent (SNP) | VAF 35/136 reads (26%) | called by muse, mutect2, varscan2
- OR4S2 | c.702C>T p.A234= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100412666; called by muse, mutect2, varscan2
- PHF2 | c.3228G>T p.A1076= | Silent (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2, varscan2
- POLE | c.5514C>T p.H1838= | Silent (SNP) | VAF 27/147 reads (18%) | catalogued as rs936176137; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPIL1 | c.465C>T p.D155= | Silent (SNP) | VAF 67/312 reads (21%) | catalogued as rs758011110, COSV65472845; called by muse, mutect2, varscan2
- RGS12 | c.2415G>A p.E805= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as rs771350917; called by muse, varscan2
- SPANXN4 | c.64A>C p.R22= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- TDRD5 | c.297G>A p.K99= | Silent (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- TLX2 | c.462T>A p.P154= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- TRHR | c.972C>T p.S324= | Silent (SNP) | VAF 51/304 reads (17%) | catalogued as rs1422657684; called by muse, mutect2, varscan2
- TTC34 | c.2286G>A p.E762= | Silent (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- VNN1 | c.600T>C p.N200= | Silent (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- ZNF274 | c.897G>A p.E299= (on ENST00000610905; = p.E194= on NM_016324.3) | Silent (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2, varscan2
- C22orf34 | n.153C>T | RNA (SNP) | VAF 48/235 reads (20%) | catalogued as rs893078168; called by muse, mutect2, varscan2
- EIF2B4 | c.*25T>C | 3'UTR (SNP) | VAF 58/311 reads (19%) | called by muse, mutect2, varscan2
- GVINP1 | n.2147dup | RNA (INS) | VAF 14/122 reads (11%) | called by mutect2, pindel
- HSP90AA4P | n.1201A>T | RNA (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- MCF2L | c.170-46144C>G | Intron (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156967 C>T | 3'Flank (SNP) | VAF 14/169 reads (8%) | catalogued as rs782641486; called by muse, mutect2
- RALGPS1 | c.910+9151G>T | Intron (SNP) | VAF 33/226 reads (15%) | called by muse, mutect2, varscan2
- SERPINB13 | c.473-188A>C | Intron (SNP) | VAF 46/245 reads (19%) | called by muse, mutect2, varscan2
- SLC5A1 | c.886-15G>A | Intron (SNP) | VAF 68/463 reads (15%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.925G>C | RNA (SNP) | VAF 9/215 reads (4%) | called by muse, mutect2
- TLCD3B | c.540+9G>A | Intron (SNP) | VAF 74/390 reads (19%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34579112 C>A | 5'Flank (SNP) | VAF 36/165 reads (22%) | called by muse, mutect2, varscan2
